Somatic mutation profile of tumor specimen PCProject_0028_T2_WES (aliquot PCProject_0028_T2_WES_1) from CMI case PCProject_0028, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.9 years (22,602 days).
Specimen PCProject_0028_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96df57e7-4ca8-4848-adce-24e87a523f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0028_BLOOD_BC (Blood Derived Normal), aliquot PCProject_0028_BLOOD_BC_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d16b500-877a-44d9-a7dd-589871c4c3c0

The open-access MAF lists 45 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 10, Silent 4, Nonsense Mutation 3, 3'UTR 3, 3'Flank 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 31/140 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV61653339, COSV61655858; called by muse, mutect2, varscan2
- APH1A | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs782208863; called by muse, mutect2, varscan2
- CASP8AP2 | c.4511G>A p.S1504N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52747151; called by mutect2, varscan2
- FBXW4 | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as rs753881830; called by mutect2, varscan2
- FLG | c.7250A>G p.Q2417R | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV64237427; called by muse, mutect2, varscan2
- INTS8 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 35/136 reads (26%) | catalogued as rs772313834, COSV58248752; called by muse, mutect2, varscan2
- LAMB2 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as rs1174151944, COSV59739111; called by muse, mutect2
- PCDH11Y | c.3443C>T p.P1148L | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs374229187, COSV53087801; called by muse, mutect2
- TFE3 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs782666638; called by muse, mutect2
- TSC1 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53771884; called by muse, mutect2, varscan2
- TTN | c.76723C>T p.R25575C (on ENST00000591111; = p.R18151C on NM_003319.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | PolyPhen probably damaging (0.998); catalogued as rs756815015, COSV59899329; called by mutect2, varscan2
- CELSR3 | c.5154C>G p.G1718= | Splice Region (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2
- CTAGE1 | c.1970G>A p.G657D | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2
- ELK4 | c.345C>G p.S115R | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- FOXO3 | c.481T>C p.S161P | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HLCS | c.1892T>A p.L631* | Nonsense Mutation (SNP) | VAF 89/398 reads (22%) | called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.031); called by muse, mutect2
- MYO5B | c.3522C>G p.D1174E | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NINL | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PACSIN2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTPRG | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTTG2 | c.467A>T p.E156V | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM5 | c.2029G>T p.D677Y | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- RGPD3 | c.4036G>T p.E1346* | Nonsense Mutation (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- SYT3 | c.643C>G p.Q215E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2
- ZNF691 | c.821A>G p.Q274R (on ENST00000372502; = p.Q243R on NM_015911.3) | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ADCY5 | c.3699C>T p.Y1233= | Silent (SNP) | VAF 60/202 reads (30%) | called by muse, mutect2, varscan2
- ADCY5 | c.1914G>A p.E638= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as rs377549844; called by muse, mutect2, varscan2
- KANK4 | c.237G>C p.G79= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- THAP6 | c.249T>C p.L83= | Silent (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- ARHGAP8 | c.299+278T>C | Intron (SNP) | VAF 8/74 reads (11%) | catalogued as rs1199925933, COSV104396514; called by muse, varscan2
- ARSD | c.439+106A>G | Intron (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- CASP8 | chr2:201286642 A>G | 3'Flank (SNP) | VAF 6/62 reads (10%) | catalogued as COSV51858093; called by muse, mutect2
- CNGA1 | c.-15+10412A>G | Intron (SNP) | VAF 8/88 reads (9%) | catalogued as rs1393881531, COSV62054954; called by muse, varscan2
- CREBRF | c.1418-133A>G | Intron (SNP) | VAF 18/108 reads (17%) | called by muse, varscan2
- DLG1 | c.2005-753C>A | Intron (SNP) | VAF 28/170 reads (16%) | catalogued as rs1048707041; called by muse, mutect2, varscan2
- EFHC1 | c.*1302A>G | 3'UTR (SNP) | VAF 8/79 reads (10%) | called by muse, varscan2
- MBD3 | c.*2898A>G | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by mutect2, varscan2
- NRIP3 | c.*519C>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- RAD51 | c.225+714T>C | Intron (SNP) | VAF 8/50 reads (16%) | catalogued as rs777467455; called by muse, varscan2
- RBL2 | c.993-400A>G | Intron (SNP) | VAF 10/74 reads (14%) | catalogued as rs1426585233; called by muse, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 10/120 reads (8%) | catalogued as rs910081914; called by muse, mutect2
- TYK2 | c.194-1368T>C | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as rs1386730107; called by muse, mutect2, varscan2
- ZNF468 | c.-10G>T | 5'UTR (SNP) | VAF 30/175 reads (17%) | called by muse, mutect2, varscan2
- ZNF85 | c.229+2251T>G | Intron (SNP) | VAF 6/82 reads (7%) | catalogued as rs1366989750; called by muse, mutect2
